Somatic mutation profile of tumor specimen C3N-00822-01 (aliquot CPT0087820009) from CPTAC case C3N-00822, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.5 years (19,536 days).
Specimen C3N-00822-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0f3a13c-68e7-4b9a-9963-d370995c83ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00822-31 (Blood Derived Normal), aliquot CPT0087880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee0bd07-4e16-42ac-95fe-f2b940bfcaea

The open-access MAF lists 113 somatic variants for this specimen: 79 protein-altering or splice-affecting, 19 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Intron 11, Nonsense Mutation 7, Frame Shift Ins 4, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, 5'Flank 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2311A>C p.S771R | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.402); catalogued as COSV70025481; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3540G>A p.M1180I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1367294073; called by muse, mutect2, varscan2
- ADRA2C | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV100342408; called by muse, mutect2
- CACNA1E | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62394720; called by muse, mutect2
- CELF6 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs749663605; called by muse, mutect2, varscan2
- CFAP47 | c.8799A>C p.E2933D | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV66221008; called by muse, mutect2, varscan2
- COL6A5 | c.7057T>C p.C2353R (on ENST00000312481; = p.C2349R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as rs746594305; called by muse, mutect2, varscan2
- CST9L | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100980825; called by muse, mutect2, varscan2
- DHRS9 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs201781895; called by muse, mutect2, varscan2
- DOK5 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1568781559, COSV52815932; called by muse, mutect2, varscan2
- FAT1 | c.555C>A p.Y185* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV71674910; called by mutect2, varscan2
- FER | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99813521; called by mutect2, varscan2
- KCNH5 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs1282339448, COSV100526701; called by muse, mutect2, varscan2
- KLHL34 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV65278771; called by muse, mutect2, varscan2
- LAMB4 | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs201807198, COSV52724952; called by muse, mutect2, varscan2
- LRP2 | c.11041T>G p.F3681V | Missense Mutation (SNP) | VAF 81/536 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.167); catalogued as rs759810477; called by muse, mutect2, varscan2
- MAGEE1 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63912170; called by muse, mutect2, varscan2
- MORN5 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 105/237 reads (44%) | catalogued as COSV61346432; called by muse, mutect2, varscan2
- MS4A1 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 89/342 reads (26%) | catalogued as COSV100619394; called by muse, mutect2, varscan2
- MTX2 | c.422C>G p.T141S | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as rs748581416; called by muse, mutect2, varscan2
- NME8 | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV99552922; called by muse, mutect2, varscan2
- NRG3 | c.1208A>C p.K403T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV104427196, COSV64543708; called by muse, mutect2, varscan2
- NSD3 | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 179/462 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs972730167; called by muse, mutect2, varscan2
- PDP2 | c.1279G>C p.V427L | Missense Mutation (SNP) | VAF 100/392 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs773595909; called by muse, mutect2, varscan2
- PEG3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV55643022; called by muse, mutect2, varscan2
- PWP1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs368748715; called by muse, mutect2, varscan2
- SHANK2 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 53/974 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555153078, COSV53598837; called by muse, mutect2
- SLC35B2 | c.1224_1225del p.R408Sfs*18 | Frame Shift Del (DEL) | VAF 46/234 reads (20%) | catalogued as rs757164153; called by pindel, varscan2
- TMEM160 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs555363068, COSV53409562; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 173/509 reads (34%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TRIM10 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 118/302 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as rs146058085; called by muse, mutect2, varscan2
- TTBK1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs745618169, COSV52491503; called by muse, mutect2, varscan2
- UTRN | c.5593T>A p.S1865T | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs756621951; called by muse, mutect2
- VRTN | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as rs780120752; called by muse, mutect2, varscan2
- WDR25 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 82/331 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV58936848; called by muse, mutect2, varscan2
- ZFR | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.622); catalogued as rs749027953; called by muse, mutect2, varscan2
- ZKSCAN5 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs776983818; called by muse, mutect2, varscan2
- ADAM10 | c.1254dup p.A419Cfs*10 | Frame Shift Ins (INS) | VAF 47/238 reads (20%) | called by mutect2, pindel, varscan2
- AGT | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 219/746 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- AMY1C | c.1027A>T p.M343L | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); called by muse, mutect2
- BRWD3 | c.3602+1G>A p.X1201_splice | Splice Site (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- C8A | c.460T>G p.L154V | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CALCRL | c.367A>C p.N123H | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP46 | c.2924+4A>C | Splice Region (SNP) | VAF 43/316 reads (14%) | called by muse, mutect2, varscan2
- CIITA | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COPA | c.2945A>T p.Y982F | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPT1B | c.2222C>G p.S741* | Nonsense Mutation (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- CRIM1 | c.2654_2656del p.P885_I886delinsL | In Frame Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- DCAF4L2 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 100/428 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAH11 | c.4799T>G p.L1600R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT1 | c.553dup p.Y185Lfs*5 | Frame Shift Ins (INS) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- FOXC1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, varscan2
- HOOK2 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- KHDRBS2 | c.262T>G p.L88V | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); called by muse, mutect2
- KMT2D | c.10131dup p.S3378Ifs*45 | Frame Shift Ins (INS) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- LIFR | c.2350A>C p.K784Q | Missense Mutation (SNP) | VAF 33/505 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- MDGA2 | c.2009T>C p.L670P (on ENST00000399232 / NM_001113498.2; = p.L372P on NM_182830.4) | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MMRN2 | c.1412_1413insTT p.N472Sfs*19 | Frame Shift Ins (INS) | VAF 55/239 reads (23%) | called by mutect2, pindel, varscan2
- MXRA8 | c.1285T>C p.Y429H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2
- NFASC | c.1232C>A p.S411Y (on ENST00000339876 / NM_001378329.1; = p.S422Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NOTCH2 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 194/402 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G2C | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PLCB4 | c.99del p.F33Lfs*16 | Frame Shift Del (DEL) | VAF 21/164 reads (13%) | called by mutect2, pindel, varscan2
- POTEC | c.768A>C p.K256N | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTPRD | c.193A>C p.S65R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RNLS | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SHPRH | c.4629T>G p.I1543M (on ENST00000275233 / NM_001042683.3; = p.I1547M on NM_173082.3) | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC25A38 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 120/391 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC5A12 | c.1783C>A p.L595M | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SOX1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SPAG1 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TAB3 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2
- TCEA3 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TEX13C | c.1532T>A p.V511E | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TEX55 | c.1089T>A p.Y363* | Nonsense Mutation (SNP) | VAF 80/279 reads (29%) | called by muse, mutect2, varscan2
- TLR4 | c.1805T>C p.V602A (on ENST00000355622 / NM_138554.5; = p.V562A on NM_003266.4) | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2
- TMCO3 | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 53/242 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TTC28 | c.4744T>A p.S1582T | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF791 | c.810A>T p.R270S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ARID1A | c.2841A>G p.P947= | Silent (SNP) | VAF 51/232 reads (22%) | catalogued as rs778920555; called by muse, mutect2, varscan2
- BABAM1 | c.204C>T p.A68= | Silent (SNP) | VAF 39/260 reads (15%) | catalogued as rs372050396; called by muse, mutect2, varscan2
- CD33 | c.42C>T p.A14= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- CDH15 | c.1575C>T p.L525= | Silent (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- CLCNKB | c.1995G>T p.V665= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.1038G>A p.A346= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- IDH1 | c.90C>T p.L30= | Silent (SNP) | VAF 38/257 reads (15%) | catalogued as rs1431581254; called by muse, mutect2, varscan2
- KLHL34 | c.462C>A p.I154= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV101069880; called by muse, mutect2, varscan2
- KLK7 | c.33C>T p.I11= | Silent (SNP) | VAF 50/221 reads (23%) | called by muse, mutect2, varscan2
- LAMC1 | c.3048A>G p.E1016= | Silent (SNP) | VAF 72/318 reads (23%) | called by muse, mutect2, varscan2
- NCOR1 | c.5154G>A p.R1718= | Silent (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- NEK11 | c.1650A>G p.E550= | Silent (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- NELL2 | c.624C>T p.V208= | Silent (SNP) | VAF 35/292 reads (12%) | called by muse, mutect2, varscan2
- OR1J2 | c.496C>T p.L166= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- SEMG2 | c.1374G>A p.E458= | Silent (SNP) | VAF 136/417 reads (33%) | catalogued as rs1331183326; called by muse, mutect2, varscan2
- SLIT2 | c.2514T>C p.S838= | Silent (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- YIPF7 | c.82T>C p.L28= | Silent (SNP) | VAF 68/297 reads (23%) | catalogued as COSV60657676; called by muse, mutect2, varscan2
- ZMYND11 | c.1638G>A p.L546= | Silent (SNP) | VAF 62/309 reads (20%) | called by muse, mutect2, varscan2
- ZNF233 | c.174A>G p.L58= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs1254888503; called by muse, mutect2
- ADAM11 | c.*138G>A | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- AP1G1 | c.-4+136A>C | Intron (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- C10orf88B | n.468C>T | RNA (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- CCDC148 | c.1110+20654A>C | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- CD164L2 | c.328+137C>T | Intron (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-644A>C | Intron (SNP) | VAF 18/120 reads (15%) | called by mutect2, varscan2
- COL21A1 | c.*49C>A | 3'UTR (SNP) | VAF 70/490 reads (14%) | called by muse, mutect2, varscan2
- CTNND1 | c.2809-35C>G | Intron (SNP) | VAF 19/98 reads (19%) | catalogued as COSV100649742; called by muse, mutect2, varscan2
- FGF12 | c.414+66682A>T | Intron (SNP) | VAF 92/186 reads (49%) | called by muse, mutect2, varscan2
- HEXA | c.347-315A>G | Intron (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- MFSD10 | c.1253-35dup | Intron (INS) | VAF 52/233 reads (22%) | called by mutect2, pindel, varscan2
- RUBCN | c.1685-51A>G | Intron (SNP) | VAF 171/332 reads (52%) | catalogued as rs747361494; called by muse, mutect2, varscan2
- TAC4 | c.123+847T>C | Intron (SNP) | VAF 43/360 reads (12%) | called by muse, mutect2, varscan2
- TMEM150C | chr4:82562197 C>A | 5'Flank (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- WASHC4 | c.2515-26_2515-23delinsTTTT | Intron (ONP) | VAF 6/64 reads (9%) | called by mutect2*, pindel
